Somatic mutation profile of tumor specimen BA2681D (aliquot aq-BA2681D) from BEATAML1.0 case 2288, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,143 days).
Specimen BA2681D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b395ea1c-b77b-4f38-bd3c-4a72eda8cab0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2223D (Solid Tissue Normal), aliquot aq-BA2223D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79aac232-77ee-4842-88d7-3d856ab59dda

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Splice Site 2, Splice Region 1, Intron 1, Frame Shift Del 1, 3'UTR 1, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.1628G>A p.G543D | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs767226511, COSV53045034, COSV53051884, COSV99258949; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APCDD1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1212065765, COSV62371989; called by muse, mutect2, varscan2
- TLR2 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1173378845; called by muse, mutect2, varscan2
- C1orf127 | c.696G>T p.V232= | Splice Region (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- CBL | c.1228-41_1229del p.X410_splice | Splice Site (DEL) | VAF 52/118 reads (44%) | called by mutect2, pindel
- CTCF | c.782-2A>C p.X261_splice | Splice Site (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- FOXO6 | c.617C>A p.A206E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2
- IARS1 | c.3100T>G p.F1034V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCEH1 | c.215del p.F72Sfs*7 (on ENST00000538775; = p.F40Sfs*7 on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/122 reads (23%) | called by mutect2, varscan2
- RAC2 | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFNB1 | c.927A>G p.T309= | Silent (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- HDAC4 | c.1776+37C>T | Intron (SNP) | VAF 30/83 reads (36%) | catalogued as rs771617717; called by muse, varscan2
- PEG10 | c.*1028T>C | 3'UTR (SNP) | VAF 33/166 reads (20%) | called by muse, mutect2, varscan2
- PRSS30P | n.2923C>T | RNA (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2
